Gene-level copy-number profile of specimen HCM-WCMC-1280-C54-85A from HCMI case HCM-WCMC-1280-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 63.1 years (23,032 days).
Specimen HCM-WCMC-1280-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0fdbf384-0ed2-4ce0-8198-b999f3b9ea90.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-1280-C54-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/182ad707-e4d6-4b87-8149-4d13653af7bf

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 430; copy number 2: 12,939; copy number 3: 28,462; copy number 4: 13,568; copy number 5: 595; copy number 6: 1,636; copy number 7: 343; copy number 8: 193; copy number 9: 6; copy number 10: 38; copy number 11: 17; copy number 12: 89; copy number 19: 11; copy number 20: 51.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 748 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,918,469–32,198,285, 41 genes, copy number 7: RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1, AC114495.1, NKAIN1, SNRNP40, AC114495.2, ZCCHC17, AL451070.1, FABP3, SERINC2, AC209007.1, RNU6-40P, LDC1P, Y_RNA, LINC01226, AC114488.1, TINAGL1, HCRTR1, PEF1, PEF1-AS1, AC114488.2, COL16A1, ADGRB2, MIR4254, AL354919.2, SPOCD1, AL354919.1, AL136115.2, PTP4A2, AL136115.1, KHDRBS1, AL445248.1, TMEM39B, MIR5585, Metazoa_SRP, KPNA6, AL049795.2, TXLNA.
- chr2:67,397,322–68,397,453, 17 genes, copy number 11: ETAA1, LINC02831, AC007422.1, AC010987.1, LINC01812, FBXL12P1, C1D, WDR92, PPIAP64, AC017083.3, PNO1, PPP3R1, AC017083.2, AC017083.1, CNRIP1, AC015969.1, PLEK.
- chr3:169,083,499–169,998,373, 24 genes, copy number 8: MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1.
- chr5:36,151,989–37,066,413, 14 genes, copy number 7: SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL, KRT18P31.
- chr8:97,241,742–103,002,424, 133 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:143,684,452–143,713,898, 1 gene, copy number 8 (within-gene range 6–8): ZNF707.
- chr8:143,706,694–144,063,965, 25 genes, copy number 8–12: CCDC166, AC105219.2, MAPK15, AC105219.1, FAM83H, MIR4664, IQANK1, AC105219.3, SCRIB, MIR937, PUF60, AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1, PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846.
- chr17:55,842,677–55,872,939, 1 gene, copy number 7 (within-gene range 6–7): AC090618.1.
- chr18:63,389,190–63,422,483, 2 genes, copy number 7: VPS4B, AC036176.2.
- chr19:9,278,448–15,332,545, 347 genes, copy number 7–20 (broad region; genes not listed).
- chr20:2,453,010–4,431,732, 69 genes, copy number 8–10 (broad region; genes not listed).
- chr20:34,194,569–35,412,031, 46 genes, copy number 7–10: ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1.
- chr20:35,615,829–35,742,312, 9 genes, copy number 8: SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39.
- chr20:63,272,785–63,628,824, 19 genes, copy number 7–9: ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR.

Autosomal genes at a single copy (total copy number 1): 430. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
